Somatic mutation profile of tumor specimen TCGA-N5-A4RU-01A (aliquot TCGA-N5-A4RU-01A-31D-A28R-08) from TCGA case TCGA-N5-A4RU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Age at diagnosis: 54.8 years (20,025 days).
Specimen TCGA-N5-A4RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c419fe70-d81d-4db3-ba94-701334bcd870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RU-10A (Blood Derived Normal), aliquot TCGA-N5-A4RU-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9c71df-17d7-4c82-9470-20093d90d712

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 10, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 57/65 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 30/37 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.6325C>T p.R2109C | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684555; called by muse, mutect2, varscan2
- B3GALT5 | c.650C>G p.T217S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1271263632, COSV58199115; called by muse, mutect2, varscan2
- CDK11B | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1293507267; called by mutect2, varscan2
- CNPY1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV58786479; called by muse, mutect2, varscan2
- CNTN5 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs199796384, COSV54331157, COSV99675626; called by muse, mutect2, varscan2
- DOP1A | c.2320C>A p.R774S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99380919; called by muse, mutect2, varscan2
- DROSHA | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1186040397, COSV100757688; called by muse, mutect2
- DTNA | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs368868084; called by muse, mutect2, varscan2
- GRM6 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs369887161; called by muse, mutect2, varscan2
- KLKB1 | c.1835C>A p.T612N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52999392; called by muse, mutect2, varscan2
- LRP1 | c.4282C>T p.R1428W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs745902553, COSV99675393; called by muse, mutect2, varscan2
- MICOS13 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV56799807; called by muse, mutect2, varscan2
- NPNT | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs757784960; called by muse, mutect2, varscan2
- NWD1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764495804, COSV60341670; called by muse, mutect2, varscan2
- PCDH15 | c.5215A>G p.S1739G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64738591; called by muse, mutect2, varscan2
- PLXNA3 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782421628; called by muse, mutect2, varscan2
- RESF1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1159976283; called by muse, mutect2, varscan2
- SAMD4B | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58750994; called by muse, mutect2
- SLC5A1 | c.827G>T p.W276L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as CM961325; called by muse, mutect2
- SLF2 | c.2333+1G>A p.X778_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as rs748162172, COSV53279940; called by muse, mutect2, varscan2
- SNED1 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572761965, COSV54087860, COSV54090683; called by muse, mutect2, varscan2
- TLN2 | c.5872G>A p.V1958I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs375769813; called by muse, mutect2, varscan2
- TMPRSS15 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375777008; called by muse, mutect2, varscan2
- TYR | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs61754379, CM971548, COSV54470028; ClinVar: not provided; called by muse, mutect2, varscan2
- ALPK1 | c.3287_3316del p.N1096_P1105del | In Frame Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- APEX2 | c.1065_1068del p.T356Cfs*37 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- BCL2L11 | c.561dup p.R188Tfs*77 (on ENST00000393256 / NM_138621.5; = p.R128Tfs*77 on NM_006538.5) | Frame Shift Ins (INS) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- BRCC3 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- C2CD6 | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK10 | c.1009A>C p.T337P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CNR1 | c.450G>C p.R150S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- EFNB2 | c.217T>G p.Y73D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ENC1 | c.199T>C p.C67R | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FAM160B1 | c.1668C>G p.H556Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by muse, mutect2
- FCRL1 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRAS1 | c.5605G>C p.D1869H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPC3 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNAB1 | c.511C>T p.L171F (on ENST00000490337 / NM_172160.3; = p.L160F on NM_003471.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KMT2C | c.6295del p.T2100Pfs*6 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2*
- LRCH1 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- MAN2A2 | c.62C>G p.S21W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP2 | c.1053C>A p.F351L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- MPZL3 | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PEAK1 | c.1166G>C p.S389T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNPT1 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPP2R1A | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RPS28 | c.204G>C p.L68F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- TTN | c.8267C>G p.S2756C (on ENST00000591111; = p.S2710C on NM_003319.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- UXS1 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- VPS18 | c.1271C>G p.T424R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.069); called by muse, mutect2
- WDR13 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ZNF33A | c.1748A>T p.H583L (on ENST00000458705 / NM_006974.3; = p.H584L on NM_006954.2) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNF585A | c.181A>G p.S61G (on ENST00000292841 / NM_001288800.2; = p.S6G on NM_152655.3) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF780A | c.1822A>C p.T608P | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- CEACAM5 | c.1509C>G p.P503= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- CFAP100 | c.153G>A p.A51= | Silent (SNP) | VAF 67/201 reads (33%) | catalogued as rs771764804, COSV61502736, COSV61504088; called by muse, mutect2, varscan2
- DSP | c.7866C>T p.I2622= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- GPATCH8 | c.669A>G p.V223= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- GPX3 | c.207G>A p.V69= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1430868908; called by muse, mutect2, varscan2
- HMGN3 | c.78G>C p.R26= | Silent (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- IFIT1 | c.732A>G p.L244= | Silent (SNP) | VAF 107/172 reads (62%) | called by muse, mutect2, varscan2
- NAA15 | c.849C>T p.A283= | Silent (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- NLRC3 | c.1485C>T p.F495= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1329613965; called by muse, varscan2
- SART1 | c.96C>T p.H32= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs755434498; called by muse, mutect2
- MBD1 | c.*33-231G>T | Intron (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- MIR668 | n.52G>A | RNA (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6494G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs369276902; called by mutect2, varscan2
